Surgical pathology report (de-identified scan), TCGA case TCGA-EP-A12J, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-EP-A12J-01A (Primary Tumor).

105-0-3

Carcinoma, hepatocellular, NOS

3170/3

lw
11/22/10

Site: Liver c22.0

SPECIMEN

Left lateral segment liver

CLINICAL NOTES

PRE-OP DIAGNOSIS: Hepatocellular carcinoma.

GROSS DESCRIPTION

Received fresh, subsequently fixed in formalin, labeled
"left lateral segment liver" is a 310 gm, 14 x 8.5 x 5.5

cm

wedge of liver. The surface of the specimen is violaceous, pink, smooth, glistening, diffusely granular and nodular. There is a 2.5 cm nodule coming to within 3 cm of the stapled margin. The edge is inked green and the specimen is sectioned to show a 2.7 x 2.7 x 2.7 cm yellow-tan, well circumscribed nodule. This comes within 1.3 cm of the nearest surgical margin (inked blue). The remainder of the specimen is sectioned to show a tan-brown smooth glistening cut surface. Representative sections of the specimen are submitted in

8

cassettes as follows: Block 1 - representative normal; block 2-4 - tumor to surface and normal; block 5 - stapled edge at stapled margin; blocks 7-8 - tumor to surgical margin.

MICROSCOPIC DESCRIPTION

Histologic type: Hepatocellular carcinoma

Histologic grade: Well differentiated

Tumor size: 2.7 cm

Margins of resection: Uninvolved

Vascular invasion: None identified

Regional lymph nodes (pN): None submitted (pNX)

Distant metastasis (pM): Could not be evaluated by this specimen (pMX)

Other findings: The hepatocellular carcinoma is arising in a background of micronodular cirrhosis.

DIAGNOSIS

Liver, left lateral segment, partial hepatectomy.

Hepatocellular carcinoma, well differentiated, 2.7 cm, margins uninvolved.

, M.D., (Electronic Signature)

--- End Of Report ---

UUID: CC7D4052-0068-425B-ASC3-873059716D44

IIA Discrepancy		

Source: NCI Genomic Data Commons file 3d79b0a0-83ad-4b15-bb98-34732a41cfae (TCGA-EP-A12J.CC7D4052-0068-425B-A5C3-873059716D44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).